Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A1CU, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A1CU-01A (Primary Tumor).

[page 1 of 2]
100-0-3
Carcinoma, papillary, thyroid 8260/3
Site Code: Thyroid, NOS C73.9

1/9/11
lw

Surgical Pathology Consultation Report

Patient Name:

MRN:

DOB:

Gender: M

HCN:

Ordering MD:

Copy To:

Service:

Visit #:

Location:

Facility:

Accession #:

Collected:

Received:

Reported:

Specimen(s) Received

1. Thyroid: total thyroid central compartment and superior mediastinal lymph node; stitch at rt. superior pole of thyroid
2. Neck: Contents of left neck, levels 2,3 and 4

Diagnosis

1. Multifocal papillary carcinoma, dominant left 6.5 cm: Thyroid
No pathological diagnosis: Lymph nodes, 15
- total thyroidectomy specimen

Metastatic papillary thyroid carcinoma: Lymph node, 1 of 5 (left neck) dissection specimen

Synoptic Data

Specimen Type: Total thyroidectomy & left neck dissection
Tumour Focality: Multifocal
-----Dominant Tumour-----
Histologic Type: Papillary carcinoma, classical type
Tumour Site: Left Lobe
Tumour Size: Greatest Dimension: 6.5 cm
Additional Dimensions: 3.4 x 2.6 cm
Capsular Invasion: Encapsulated
Extrathyroidal Extension: Widely invasive
Margins: Absent
Venous/Lymphatic (Large/Small Vessel) Invasion (V/L): Absent
-----Secondary Tumour-----
Histologic Type: Papillary carcinoma, classical type
Tumour Site: Right Lobe
Tumour Size: Greatest Dimension: 0.4 cm
Capsular Invasion: Unencapsulated
Extrathyroidal Extension: Locally invasive
Margins: Absent
Venous/Lymphatic (Large/Small Vessel) Invasion (V/L): Absent

Reviewed/Signatures	3/1/11	

Pathologic Staging (pTNM):

pT3: Tumor more than 4 cm, limited to thyroid or with minimal extrathyroidal extension (eg, extension to sternothyroid muscle or perithyroid soft tissues)

[page 2 of 2]
Surgical Pathology Consultation Report

pN1a: Nodal metastases to Level VI (pretracheal, paratracheal and prelaryngeal/Delphian) lymph nodes

Number of regional lymph nodes examined: 20

Number of regional lymph nodes involved: 1

pMX: Distant metastasis cannot be assessed

Additional Pathologic Findings: None Identified

*Pathologic Staging is based on AJCC/UICC TNM, 6th Edition

Electronically verified by:

Clinical History

ca thyroid

Gross Description

1. The specimen labeled with the patient's name and as "total thyroid, central compartment and superior many S. no lymph node, stitch at right superior pole of thyroid" consists of a thyroid gland that is oriented with a suture and weighs 65.2 g. The right lobe measures 4.9 cm SI x 2.5 cm ML x 1.6 cm AP, the left lobe measures 7.5 cm SI x 3.4 cm ML x 3.0 cm AP and the isthmus measures 4.0 cm SI x 1.2 cm ML x 0.4 cm AP. The external surfaces have fibrous adhesions. Eight lymph nodes are identified grossly and measure from 0.3 to 0.8 cm in greatest dimension. The external surface is painted with Silver nitrate. The left lobe contains a well-delineated multi-lobulated and partially cystic brown-tan nodule that measures 6.5 cm SI x 3.4 cm ML x 2.6 cm AP. The right lobe contains a well delineated, tan nodule that measures 0.4 cm SI x 0.4 cm ML x 0.3 cm AP. The remainder of the thyroid tissue is grossly unremarkable. Sections of left lobe nodule and normal tissue from the right lobe are stored frozen. The remainder of the specimen is submitted as follows:

1K right lobe, superior to inferior

1L-P isthmus

1Q-Y left lobe, representative sections, superior to inferior (1R-S; 1T-U; 1V-W one section bisected in each)

1Z-AA multiple lymph nodes in each block

2. The specimen labeled with the patient's name and as "contents left neck level 2, 3 and 4" consists of a piece of fibroadipose tissue that measures 5.1 x 3.5 x 2.1 cm and contains multiple lymph nodes that range from 0.4 to 1.2 cm. There is also a piece of skeletal muscle that measures 4.8 x 1.4 x 0.6 cm and is grossly unremarkable. Representative sections are submitted.

2A skeletal muscle

2B multiple nodes

2C one node bisected

Source: NCI Genomic Data Commons file 0c8c201b-e25c-4145-a2d4-48b0eeb7e888 (TCGA-EM-A1CU.6518F35E-3650-4E17-8FC5-23E5BC825576.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).